Somatic mutation profile of tumor specimen ALCH-B4Y4-TTP1-A (aliquot ALCH-B4Y4-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4Y4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.7 years (26,905 days).
Specimen ALCH-B4Y4-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c989705-fbe7-42fe-8f7f-de1fc16cbd43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4Y4-NB1-A (Blood Derived Normal), aliquot ALCH-B4Y4-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a1a7c77-1668-4b86-9701-31470b20b632

The open-access MAF lists 45 somatic variants for this specimen: 29 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 11, Intron 4, Nonsense Mutation 3, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCYAP1R1 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 42/606 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.042); catalogued as rs779140594, COSV58443459; called by muse, mutect2
- ASAH1 | c.746A>G p.Y249C | Missense Mutation (SNP) | VAF 46/582 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV50501741; called by muse, mutect2
- AVPR1A | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 22/367 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs1196990220, COSV54547261; called by muse, mutect2
- MPP7 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 24/458 reads (5%) | catalogued as COSV61731408; called by muse, mutect2
- SCRT1 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 98/559 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100146361; called by muse, mutect2, varscan2
- SHROOM2 | c.3259G>A p.V1087M | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs745337866, COSV66607450; called by muse, mutect2, varscan2
- SMAD3 | c.1250C>G p.P417R | Missense Mutation (SNP) | VAF 48/578 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59280191; called by muse, mutect2
- ZBTB40 | c.2151G>T p.L717F | Missense Mutation (SNP) | VAF 30/341 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.157); catalogued as COSV65146404; called by muse, mutect2
- ZBTB40 | c.2152C>T p.P718S | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as rs748065450, COSV100988949; called by muse, mutect2
- ZHX2 | c.2176G>A p.V726M | Missense Mutation (SNP) | VAF 115/535 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1305826807; called by muse, mutect2, varscan2
- AKAP6 | c.5777A>C p.E1926A | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2
- ANKH | c.1250T>C p.V417A | Missense Mutation (SNP) | VAF 52/1085 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.162); called by muse, mutect2
- BRD4 | c.1773G>A p.M591I | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- CACNA1D | c.3584A>T p.Q1195L (on ENST00000350061 / NM_001128840.3; = p.Q1215L on NM_000720.4) | Missense Mutation (SNP) | VAF 70/517 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- CAMK2A | c.473G>C p.G158A | Missense Mutation (SNP) | VAF 95/651 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLDN34 | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.01); called by muse, mutect2
- DAB2 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 26/703 reads (4%) | called by muse, mutect2
- FAM47C | c.1055C>A p.S352Y | Missense Mutation (SNP) | VAF 38/592 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- NEXMIF | c.3769A>T p.T1257S | Missense Mutation (SNP) | VAF 34/402 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2
- PAGR1 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 32/313 reads (10%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); called by muse, mutect2
- PCARE | c.2080G>T p.D694Y | Missense Mutation (SNP) | VAF 126/1169 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- PCDHAC1 | c.2798A>G p.E933G | Missense Mutation (SNP) | VAF 35/760 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- QSER1 | c.98-11_117del p.X33_splice (on ENST00000399302; = p.X162_splice on NM_001076786.3) | Splice Site (DEL) | VAF 13/106 reads (12%) | called by mutect2, pindel
- SLC26A11 | c.683A>G p.E228G | Missense Mutation (SNP) | VAF 36/457 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2
- SORL1 | c.3830A>T p.H1277L | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2
- TRPV1 | c.1642G>T p.G548C | Missense Mutation (SNP) | VAF 27/444 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- TUFT1 | c.137C>A p.A46E | Missense Mutation (SNP) | VAF 31/376 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); called by muse, mutect2
- ZDHHC23 | c.820C>T p.H274Y | Missense Mutation (SNP) | VAF 47/312 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF250 | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 130/744 reads (17%) | called by muse, mutect2, varscan2
- ATF7IP | c.846A>G p.E282= | Silent (SNP) | VAF 34/243 reads (14%) | called by muse, mutect2, varscan2
- ERBB2 | c.1401C>T p.L467= | Silent (SNP) | VAF 34/648 reads (5%) | called by muse, mutect2
- FN1 | c.927C>T p.V309= | Silent (SNP) | VAF 76/770 reads (10%) | called by muse, mutect2
- LDLRAP1 | c.744C>T p.V248= | Silent (SNP) | VAF 37/748 reads (5%) | called by muse, mutect2
- NLRP10 | c.1344T>C p.S448= | Silent (SNP) | VAF 45/758 reads (6%) | catalogued as COSV60779670; called by muse, mutect2
- PLBD2 | c.1704C>T p.S568= | Silent (SNP) | VAF 28/344 reads (8%) | catalogued as rs751704298; called by muse, mutect2
- ST7 | c.1521C>T p.Y507= (on ENST00000265437 / NM_021908.3; = p.Y484= on NM_018412.4) | Silent (SNP) | VAF 18/214 reads (8%) | called by muse, mutect2
- TMC4 | c.717C>T p.L239= (on ENST00000617472 / NM_001145303.3; = p.L233= on NM_144686.4) | Silent (SNP) | VAF 10/216 reads (5%) | catalogued as rs550033169; called by muse, mutect2
- TMEM114 | c.555C>T p.F185= | Silent (SNP) | VAF 33/744 reads (4%) | called by muse, mutect2
- TMEM63A | c.1725G>A p.L575= | Silent (SNP) | VAF 37/295 reads (13%) | called by muse, mutect2, varscan2
- TSC2 | c.1707C>T p.V569= | Silent (SNP) | VAF 28/394 reads (7%) | called by muse, mutect2
- BLK | c.1030-62G>C | Intron (SNP) | VAF 20/204 reads (10%) | catalogued as rs762715079; called by muse, mutect2, varscan2
- C11orf24 | c.-1G>A | 5'UTR (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- DACH2 | c.1240+2784G>A | Intron (SNP) | VAF 8/146 reads (5%) | catalogued as rs1388340749; called by muse, mutect2
- ST20-MTHFS | c.-12+65C>T | Intron (SNP) | VAF 12/221 reads (5%) | called by muse, mutect2
- TTYH2 | c.129+1937G>A | Intron (SNP) | VAF 56/504 reads (11%) | catalogued as rs1022116992; called by muse, mutect2, varscan2
